TCGA case TCGA-DX-A6YX — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ecc74d54-d929-4dd0-b9ec-e03163343f9a

Demographics
Sex at birth: female; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 513 days (1.4 years).

Diagnoses (4)
1. Fibromyxosarcoma (the primary disease): ICD-O-3 morphology code: 8811/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,871 days); Year of diagnosis: 2005; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: Yes; Tumor depth descriptor: Superficial.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7; Tumor length measurement: 9.5; Tumor width measurement: 8.
2. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Lung, NOS. Age at diagnosis: 68.6 years (25,071 days); Days to diagnosis: 200 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Thyroid gland. Age at diagnosis: 68.7 years (25,093 days); Days to diagnosis: 222 days; Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Bone, NOS. Age at diagnosis: 68.7 years (25,093 days); Days to diagnosis: 222 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 200 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 200 days.
- Day 222 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thyroid gland; Days to progression: 222 days.
- Day 222 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 222 days.
- Days to follow up: 513 days (1.4 years); Disease response: With Tumor.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A6YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 510 mg.
  Slide TCGA-DX-A6YX-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 17; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
- Sample TCGA-DX-A6YX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-DX-A6YX-10A, TCGA-DX-A6YX-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 8; Lesion pathologic depth: 7.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 285; Days from index date to pharmaceutical treatment ended: 407; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 292; Days from index date to pharmaceutical treatment ended: 407; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 444; Days from index date to pharmaceutical treatment ended: 484; Pharmaceutical therapy drug name: Liposomal doxorubicin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Days from index date to radiation therapy started: 85; Days from index date to radiation therapy ended: 135; Radiation therapy type: External; Radiation total dose: 6300; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.
- Radiation treatment 2: Days from index date to radiation therapy started: 235; Days from index date to radiation therapy ended: 256; Radiation therapy type: External; Radiation total dose: 3500; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 14; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 513 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 513 days; disease-free interval: event (new tumor event after initially disease-free), 200 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 200 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A6YX-01A-11D-A416-01): tumor purity 0.83, ploidy 2.94, whole-genome doublings 1.
